Somatic mutation profile of tumor specimen TARGET-10-PARDAK-09A (aliquot TARGET-10-PARDAK-09A-01D) from TARGET case TARGET-10-PARDAK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,093 days).
Specimen TARGET-10-PARDAK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f450253-7ce8-4041-a6ff-a3ddb448de6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDAK-10A (Blood Derived Normal), aliquot TARGET-10-PARDAK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d164139-7835-40e8-956b-08721c347747

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITSN2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs371930652; called by muse, mutect2, varscan2
- IGHV1-2 | c.-43C>T | 5'UTR (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
